Gene-level copy-number profile of tumor specimen TCGA-60-2715-01A from TCGA case TCGA-60-2715, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 52.0 years (18,990 days).
Specimen TCGA-60-2715-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.f1ce514d-6fa8-4f3c-b9b5-a753fb20a3fd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-60-2715-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a04add6b-09d5-4bf1-b43c-4551c6aa2047

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 27,068; copy number 2: 21,397; copy number 3: 9,103; copy number 4: 1,264; copy number 5: 549; copy number 7: 97; copy number 10: 48; copy number 11: 15; copy number 12: 194; copy number 13: 3; copy number 17: 66; copy number 21: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-60-2715-01): tumor purity 0.19, ploidy 1.93, whole-genome doublings 0 (call status: snp_call).

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:113,022,099–113,488,823, 2 genes (within-gene range 0–1): MCC, AC079465.1.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 11,336 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–154,548,147, 500 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr1:161,505,430–163,923,873, 57 genes, copy number 4: FCGR2A, AL590385.2, HSPA6, RPS23P10, FCGR3A, AL590385.1, FCGR2C, HSPA7, RPS23P9, FCGR3B, FCGR2B, AL451067.1, RPL31P11, Y_RNA, FCRLA, FCRLB, RN7SL466P, DUSP12, AL359541.1, ATF6, AL391825.1, OLFML2B, AL590408.1, NOS1AP, AL450163.1, MIR4654, AL512785.1, RNA5SP61, MIR556, AL512785.2, SPATA46, C1orf226, SH2D1B, SLAMF6P1, UHMK1, UQCRBP2, AL596325.1, UAP1, AL596325.2, DDR2, RN7SL861P, HSD17B7, CCDC190, AL392003.2, AL392003.1, RGS4, RGS5, RGS5-AS1, AL451063.1, RGS5, AL592435.1, NUF2, AL603841.1, RNA5SP62, RNA5SP63, AL355862.1, U3.
- chr1:171,841,498–172,418,466, 1 gene, copy number 4 (within-gene range 2–4): DNM3.
- chr1:172,138,397–173,603,072, 25 genes, copy number 4 (within-gene range 2–4): DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1, RNU6-157P, PIGC, C1orf105, SUCO, RNU6-693P, FASLG, SLC25A38P1, Z98043.1, AL031599.1, AIMP1P2, Z97198.1, TNFSF18, GOT2P2, AL022310.1, TNFSF4, AL645568.2, AL645568.1, PRDX6-AS1, PRDX6, SLC9C2.
- chr1:214,603,195–248,919,946, 753 genes, copy number 3 (broad region; genes not listed).
- chr2:45,388,680–48,515,391, 62 genes, copy number 13–17 (within-gene range 2–17) (broad region; genes not listed).
- chr2:54,661,011–61,018,259, 83 genes, copy number 4–17 (broad region; genes not listed).
- chr2:78,597,911–86,492,716, 118 genes, copy number 3–12 (broad region; genes not listed).
- chr3:93,843,764–186,110,318, 1,521 genes, copy number 3–12 (within-gene range 1–12) (broad region; genes not listed).
- chr4:49,588,772–61,153,962, 147 genes, copy number 3–10 (broad region; genes not listed).
- chr4:73,777,636–190,092,279, 1,571 genes, copy number 3 (broad region; genes not listed).
- chr5:58,198–32,523,865, 492 genes, copy number 3 (broad region; genes not listed).
- chr5:37,379,285–44,413,989, 119 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr6:167,607–63,779,336, 1,557 genes, copy number 3–4 (broad region; genes not listed).
- chr6:63,797,189–63,857,769, 3 genes, copy number 4: AL354719.1, SCAT8, GCNT1P4.
- chr6:66,710,242–67,467,308, 5 genes, copy number 4: AL450336.1, RNU7-66P, AL591004.1, AL365503.1, RNA5SP208.
- chr8:125,091,679–145,066,685, 366 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr11:47,905,323–54,592,409, 83 genes, copy number 3 (broad region; genes not listed).
- chr11:69,048,932–103,092,194, 704 genes, copy number 3–21 (within-gene range 2–21) (broad region; genes not listed).
- chr15:19,878,555–32,186,475, 444 genes, copy number 3 (broad region; genes not listed).
- chr16:12,545,482–35,912,516, 878 genes, copy number 3 (broad region; genes not listed).
- chr16:78,981,722–79,078,234, 4 genes, copy number 4: AC027279.3, AC027279.2, AC009145.4, AC009145.3.
- chr16:82,434,828–82,575,518, 2 genes, copy number 3: AC009117.1, AC009117.2.
- chr17:44,903,159–83,095,122, 1,218 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr18:20,946,906–23,026,488, 50 genes, copy number 3: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA.
- chr20:87,250–31,259,632, 573 genes, copy number 3–4 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 24,870. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
